Gene-level copy-number profile of tumor specimen TCGA-HS-A5NA-01A from TCGA case TCGA-HS-A5NA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 65.8 years (24,025 days).
Specimen TCGA-HS-A5NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.2798b35c-6a9f-4716-9ffc-933c1395ba87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HS-A5NA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/c607e440-5c7b-4fca-a1c2-a2c7048beef1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 12,065; copy number 2: 44,017; copy number 3: 1,971; copy number 4: 493; copy number 5: 1,243.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:239,048,168–239,401,654, 1 gene (within-gene range 0–1): HDAC4.
- chr2:239,114,858–240,025,743, 14 genes (within-gene range 0–1): AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1, AC023787.2, AC023787.3, AC023787.1, AC079612.1, AC079612.2, AC093802.2, AC093802.1, NDUFA10, MIR4786.
- chr13:48,296,162–48,711,226, 13 genes: RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,243 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,013,868–33,182,059, 55 genes, copy number 5: KHDRBS1, AL445248.1, TMEM39B, MIR5585, Metazoa_SRP, KPNA6, AL049795.2, TXLNA, CCDC28B, AL049795.1, IQCC, DCDC2B, TMEM234, EIF3I, MTMR9LP, FAM167B, LCK, Metazoa_SRP, Y_RNA, HDAC1, MARCKSL1, AL109945.1, TSSK3, FAM229A, BSDC1, GAPDHP20, AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2.
- chr1:154,199,085–205,387,440, 1,159 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:79,311,824–83,298,167, 29 genes, copy number 5: RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P.

Autosomal genes at a single copy (total copy number 1): 9,645. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
